Somatic mutation profile of tumor specimen TCGA-VM-A8CH-01A (aliquot TCGA-VM-A8CH-01A-12D-A36O-08) from TCGA case TCGA-VM-A8CH, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 24.7 years (9,005 days).
Specimen TCGA-VM-A8CH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c978118-1ab8-4e84-bd78-4b376538a7ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VM-A8CH-10A (Blood Derived Normal), aliquot TCGA-VM-A8CH-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbc046b5-2120-4d41-b6cf-deacb8175ef3

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 6, Silent 6, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 32/79 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FASN | c.5626A>G p.I1876V | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs768785119, COSV100147490; called by muse, mutect2, varscan2
- KIF24 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.56); catalogued as rs752446429, COSV100799119; called by muse, mutect2, varscan2
- NEDD4 | c.429T>G p.S143R | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.296); catalogued as COSV100163440; called by muse, mutect2, varscan2
- PDILT | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as rs372343696; called by muse, mutect2, varscan2
- REG1A | c.321G>A p.K107= | Splice Region (SNP) | VAF 30/77 reads (39%) | catalogued as COSV52071180, COSV99286689; called by muse, mutect2, varscan2
- WEE2 | c.698T>C p.L233P | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766660933, COSV101285135; called by muse, mutect2, varscan2
- ATRX | c.2546_2547del p.S849Ffs*2 | Frame Shift Del (DEL) | VAF 94/196 reads (48%) | called by pindel, varscan2
- ARHGAP32 | c.2037G>C p.R679= (on ENST00000310343 / NM_001378025.1; = p.R330= on NM_014715.4) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100087187; called by muse, mutect2, varscan2
- H2AC1 | c.297C>T p.G99= | Silent (SNP) | VAF 67/152 reads (44%) | catalogued as rs367946056; called by muse, mutect2, varscan2
- KY | c.1296G>A p.T432= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs374489792; called by muse, mutect2, varscan2
- MEGF11 | c.2016C>T p.N672= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs767950937, COSV99987114; called by muse, mutect2, varscan2
- SPDL1 | c.120A>G p.Q40= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs1212014101, COSV99517433; called by muse, mutect2, varscan2
- WDR81 | c.3756G>A p.L1252= (on ENST00000409644 / NM_001163809.2; = p.L201= on NM_152348.4) | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs1226547428, COSV100488663; called by muse, mutect2, varscan2
